Somatic mutation profile of tumor specimen 0DDDTP from CCDI case PBBNBW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 8.9 years (3,259 days).
Specimen 0DDDTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d7af1a2-14b9-4a73-b0f6-883edd407266.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDDTQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b138fca9-d454-492b-b594-cfba1970e5ad

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Intron 3, Frame Shift Del 3, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD22 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 172/481 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs778982185, COSV50054415; called by muse, mutect2, varscan2
- CLSTN2 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 50/593 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368537354, COSV101515431; called by muse, mutect2
- DCHS1 | c.3516G>C p.E1172D | Missense Mutation (SNP) | VAF 158/348 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100202070; called by muse, mutect2, varscan2
- NAPRT | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs946303445; called by muse, mutect2, varscan2
- OR11G2 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1390506490; called by muse, mutect2, varscan2
- OR5T3 | c.404A>T p.Y135F | Missense Mutation (SNP) | VAF 145/432 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV57382212; called by muse, mutect2, varscan2
- STAU2 | c.490C>T p.R164* (on ENST00000524300 / NM_001164380.2; = p.R132* on NM_014393.2) | Nonsense Mutation (SNP) | VAF 143/402 reads (36%) | catalogued as COSV63311432; called by muse, mutect2, varscan2
- ANKDD1A | c.943_944del p.S315* | Frame Shift Del (DEL) | VAF 150/377 reads (40%) | called by mutect2, varscan2
- ARFGEF2 | c.2498_2499del p.K833Rfs*10 | Frame Shift Del (DEL) | VAF 112/292 reads (38%) | called by mutect2, varscan2
- IFIT1 | c.464_465insGT p.N156* | Frame Shift Ins (INS) | VAF 126/360 reads (35%) | called by mutect2, varscan2
- LRG1 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ME1 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NCALD | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDH1 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 135/279 reads (48%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PECAM1 | c.385+4A>G | Splice Region (SNP) | VAF 155/374 reads (41%) | called by muse, mutect2, varscan2
- PKD1 | c.8435T>C p.F2812S | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PON3 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIPA1L1 | c.1195A>C p.S399R | Missense Mutation (SNP) | VAF 184/450 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by mutect2, varscan2
- TTC3 | c.3314A>C p.Q1105P | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- USP4 | c.2629A>G p.M877V | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZBTB44 | c.295_296del p.E99Kfs*4 | Frame Shift Del (DEL) | VAF 158/386 reads (41%) | called by mutect2, varscan2
- BCORL1 | c.3108G>A p.E1036= | Silent (SNP) | VAF 136/163 reads (83%) | called by muse, mutect2, varscan2
- FAT3 | c.1914A>G p.S638= | Silent (SNP) | VAF 171/444 reads (39%) | catalogued as rs1398301290; called by muse, mutect2, varscan2
- HERC2 | c.6687A>T p.G2229= | Silent (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- KRTAP19-1 | c.252C>T p.Y84= | Silent (SNP) | VAF 163/450 reads (36%) | catalogued as rs1196043751, COSV66861156; called by muse, mutect2, varscan2
- MMP11 | c.1071C>T p.F357= | Silent (SNP) | VAF 195/256 reads (76%) | catalogued as rs1380211472; called by muse, mutect2, varscan2
- NEIL3 | c.1368A>G p.E456= | Silent (SNP) | VAF 140/346 reads (40%) | catalogued as COSV52811686; called by muse, mutect2, varscan2
- SMARCB1 | c.654C>T p.I218= (on ENST00000263121; = p.I264= on NM_003073.5) | Silent (SNP) | VAF 150/347 reads (43%) | called by muse, mutect2, varscan2
- ZNF443 | c.777T>C p.S259= | Silent (SNP) | VAF 121/321 reads (38%) | catalogued as rs557760117; called by muse, mutect2, varscan2
- DCAF15 | c.1311+47C>T | Intron (SNP) | VAF 49/122 reads (40%) | catalogued as rs761109796; called by muse, mutect2, varscan2
- MCFD2 | c.149+61G>A | Intron (SNP) | VAF 73/153 reads (48%) | catalogued as rs1344553148; called by muse, mutect2, varscan2
- RTTN | c.6596-24A>T | Intron (SNP) | VAF 20/602 reads (3%) | called by muse, mutect2
- SMARCB1 | chr22:23839071 C>T | 3'Flank (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.*20C>T | 3'UTR (SNP) | VAF 113/274 reads (41%) | catalogued as rs141404066; called by muse, mutect2, varscan2
